Somatic mutation profile of tumor specimen TCGA-CJ-5682-01A (aliquot TCGA-CJ-5682-01A-11D-1534-10) from TCGA case TCGA-CJ-5682, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 60.9 years (22,244 days).
Specimen TCGA-CJ-5682-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efc7d60b-a9e9-4153-b37d-7dfd833cda66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-5682-11A (Solid Tissue Normal), aliquot TCGA-CJ-5682-11A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16980cb6-9f7d-48d2-ad6e-345a9cad3cc7

The open-access MAF lists 74 somatic variants for this specimen: 61 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 48, Silent 13, Frame Shift Del 7, Nonsense Mutation 4, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTN | c.9577C>T p.R3193* (on ENST00000591111; = p.R3147* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 90/482 reads (19%) | catalogued as rs746115846, CM157289, COSV59949359; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABT1 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51290804; called by muse, mutect2, varscan2
- ALK | c.2593T>C p.S865P | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as COSV66561962; called by muse, mutect2, varscan2
- ATP1A1 | c.1866C>G p.I622M | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV55190303; called by muse, mutect2, varscan2
- BRWD1 | c.6375A>C p.E2125D | Missense Mutation (SNP) | VAF 124/510 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.154); catalogued as COSV60893895; called by muse, mutect2, varscan2
- CCDC136 | c.3425C>T p.S1142L | Missense Mutation (SNP) | VAF 58/698 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as rs750620928, COSV52797650; called by muse, mutect2
- CCDC186 | c.752_755del p.I251Nfs*3 | Frame Shift Del (DEL) | VAF 186/1028 reads (18%) | catalogued as rs759642671; called by mutect2, pindel, varscan2
- CD163L1 | c.4129A>C p.I1377L | Missense Mutation (SNP) | VAF 236/624 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.155); catalogued as COSV58013212; called by muse, mutect2, varscan2
- CEACAM20 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 181/429 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.828); catalogued as COSV100386817, COSV57600990; called by muse, mutect2, varscan2
- CEP95 | c.174A>C p.Q58H | Missense Mutation (SNP) | VAF 113/607 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV56748436; called by muse, mutect2, varscan2
- CPXM1 | c.770A>C p.Q257P | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV66044922; called by muse, mutect2, varscan2
- DHRS7C | c.877T>C p.F293L (on ENST00000330255 / NM_001220493.2; = p.F292L on NM_001105571.3) | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57650082; called by muse, mutect2, varscan2
- DNAH1 | c.5804C>A p.A1935D | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs370590676; called by muse, mutect2, varscan2
- DNMT1 | c.3886T>C p.F1296L | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV61577565; called by muse, mutect2, varscan2
- DNPEP | c.1249G>T p.V417F | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56110438; called by muse, mutect2, varscan2
- DNPEP | c.1248G>T p.M416I | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV56110447; called by muse, mutect2, varscan2
- FAM3A | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV59194200; called by muse, mutect2, varscan2
- FMNL3 | c.1664G>A p.G555D | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV53299738; called by muse, mutect2, varscan2
- GPR85 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); catalogued as rs750940166, COSV51783039, COSV51783561; called by muse, mutect2, varscan2
- GTF2F1 | c.844C>G p.Q282E | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66725278; called by muse, mutect2, varscan2
- HERC2 | c.3028C>G p.Q1010E | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.68); catalogued as COSV55314166; called by muse, mutect2
- LRCH1 | c.1403T>C p.L468S | Missense Mutation (SNP) | VAF 162/442 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV60845126; called by muse, mutect2, varscan2
- LRRK2 | c.6505C>G p.L2169V | Missense Mutation (SNP) | VAF 108/297 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as COSV54147777; called by muse, mutect2, varscan2
- LRRK2 | c.6506T>A p.L2169Q | Missense Mutation (SNP) | VAF 109/299 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV54147799; called by muse, mutect2, varscan2
- MAP3K1 | c.605T>A p.L202* | Nonsense Mutation (SNP) | VAF 85/478 reads (18%) | catalogued as COSV68122600; called by muse, mutect2, varscan2
- MCCC1 | c.1805T>C p.V602A | Missense Mutation (SNP) | VAF 192/327 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV55607423; called by muse, mutect2, varscan2
- MUC16 | c.4477T>C p.S1493P | Missense Mutation (SNP) | VAF 140/342 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV67453862; called by muse, mutect2, varscan2
- MYO18B | c.4118T>G p.V1373G | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV59129138; called by muse, mutect2, varscan2
- NFIX | c.239G>T p.R80L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62176294, COSV62177672; called by muse, mutect2, varscan2
- NOTCH3 | c.5434del p.E1812Rfs*13 | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | catalogued as COSV99656667; called by mutect2, pindel, varscan2
- OR5F1 | c.248C>G p.A83G | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.205); catalogued as COSV53545777; called by muse, mutect2, varscan2
- PBRM1 | c.3861A>C p.E1287D (on ENST00000296302 / NM_001366071.2; = p.E1262D on NM_018313.5) | Missense Mutation (SNP) | VAF 311/544 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56267426; called by muse, mutect2, varscan2
- PDE10A | c.707A>G p.N236S | Missense Mutation (SNP) | VAF 72/303 reads (24%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.747); catalogued as rs763824170, COSV63093338; called by muse, mutect2, varscan2
- PES1 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58828129; called by muse, mutect2, varscan2
- RFPL2 | c.760G>C p.D254H | Missense Mutation (SNP) | VAF 95/275 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV50709445; called by muse, mutect2, varscan2
- RNASE12 | c.43del p.E15Kfs*4 | Frame Shift Del (DEL) | VAF 90/327 reads (28%) | catalogued as COSV100250459, COSV60087590; called by mutect2, pindel, varscan2
- ROPN1B | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV52541892; called by muse, mutect2, varscan2
- RPF2 | c.799C>T p.H267Y | Missense Mutation (SNP) | VAF 179/392 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs992435949, COSV64369119; called by muse, mutect2, varscan2
- RYR2 | c.2382C>G p.F794L | Missense Mutation (SNP) | VAF 171/854 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as COSV63672256; called by muse, mutect2, varscan2
- SDK1 | c.3439C>T p.R1147* | Nonsense Mutation (SNP) | VAF 42/321 reads (13%) | catalogued as rs750313949, COSV67357896; called by muse, mutect2, varscan2
- SETD2 | c.6371T>A p.L2124* | Nonsense Mutation (SNP) | VAF 54/88 reads (61%) | catalogued as COSV57433314; called by muse, mutect2, varscan2
- SNRPN | c.389C>G p.P130R | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100577758, COSV57594911; called by muse, mutect2
- ST14 | c.1913del p.G638Afs*124 | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | catalogued as COSV99598601; called by mutect2, varscan2
- SUV39H2 | c.892G>A p.D298N (on ENST00000354919 / NM_001193424.2; = p.D238N on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/267 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV57953170; called by muse, mutect2
- SUV39H2 | c.894C>A p.D298E (on ENST00000354919 / NM_001193424.2; = p.D238E on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV57953185; called by muse, mutect2
- TCERG1 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 80/378 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV57034986; called by muse, varscan2
- TCF12 | c.1904G>T p.R635I | Missense Mutation (SNP) | VAF 91/202 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51004486; called by muse, mutect2, varscan2
- TECPR1 | c.3111G>C p.K1037N | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV65782860; called by muse, mutect2, varscan2
- THEM5 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV64312778; called by muse, mutect2, varscan2
- TREX1 | c.628T>C p.W210R (on ENST00000625293 / NM_033629.6; = p.W200R on NM_007248.5) | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.971); catalogued as rs770775387, COSV56496610; called by muse, mutect2, varscan2
- TTN | c.41845C>A p.P13949T (on ENST00000591111; = p.P6525T on NM_003319.4) | Missense Mutation (SNP) | VAF 18/480 reads (4%) | PolyPhen probably damaging (0.999); catalogued as COSV59949336, COSV59979765; called by muse, mutect2
- UBE2H | c.344A>T p.Y115F | Missense Mutation (SNP) | VAF 260/635 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62920149; called by muse, mutect2, varscan2
- YTHDC1 | c.289A>C p.N97H | Missense Mutation (SNP) | VAF 488/1008 reads (48%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.188); catalogued as COSV60009328; called by mutect2, varscan2
- ZDHHC13 | c.1397G>T p.G466V | Missense Mutation (SNP) | VAF 406/1118 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV67980608; called by mutect2, varscan2
- COL20A1 | c.260_264del p.P87Qfs*26 | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | called by mutect2, pindel, varscan2
- EPB41L5 | c.907_918del p.L303_P306del | In Frame Del (DEL) | VAF 69/267 reads (26%) | called by mutect2, pindel, varscan2
- FBN2 | c.2811del p.D938Ifs*68 | Frame Shift Del (DEL) | VAF 18/108 reads (17%) | called by mutect2, pindel, varscan2
- HEATR9 | c.1436T>A p.L479H | Missense Mutation (SNP) | VAF 133/291 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- IGHV1-18 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- NOS1AP | c.618_619insGG p.R207Gfs*32 | Frame Shift Ins (INS) | VAF 22/56 reads (39%) | called by mutect2, pindel, varscan2
- PANK3 | c.609_610del p.D203Efs*3 | Frame Shift Del (DEL) | VAF 105/332 reads (32%) | called by mutect2, pindel, varscan2
- CDC14A | c.1455A>G p.L485= | Silent (SNP) | VAF 34/133 reads (26%) | catalogued as COSV60556322; called by muse, mutect2, varscan2
- DENND3 | c.2454C>A p.A818= | Silent (SNP) | VAF 61/122 reads (50%) | catalogued as COSV52801553; called by muse, mutect2, varscan2
- DISP3 | c.2127C>T p.L709= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV53823468; called by muse, mutect2, varscan2
- FSTL5 | c.2031C>T p.V677= | Silent (SNP) | VAF 51/247 reads (21%) | catalogued as rs1227568175, COSV60186123; called by muse, mutect2, varscan2
- LRP1 | c.7989C>A p.T2663= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV54505480; called by muse, mutect2, varscan2
- LYPD5 | c.657C>A p.T219= (on ENST00000377950 / NM_001031749.3; = p.T176= on NM_182573.2) | Silent (SNP) | VAF 118/282 reads (42%) | catalogued as COSV65020420; called by muse, mutect2, varscan2
- MYO5B | c.1242C>A p.G414= | Silent (SNP) | VAF 70/277 reads (25%) | catalogued as COSV53214204; called by muse, mutect2, varscan2
- NFATC3 | c.2244T>A p.I748= | Silent (SNP) | VAF 71/170 reads (42%) | catalogued as COSV60472034; called by muse, mutect2, varscan2
- RGS3 | c.600T>C p.A200= (on ENST00000350696 / NM_001282923.2; = p.A88= on NM_017790.4) | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs1191464489, COSV58278407; called by muse, mutect2, varscan2
- SHC3 | c.813T>G p.A271= | Silent (SNP) | VAF 66/225 reads (29%) | catalogued as COSV65437289; called by muse, mutect2, varscan2
- TESK1 | c.1053G>C p.R351= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV52410572; called by muse, mutect2, varscan2
- UNC13D | c.1155T>A p.G385= | Silent (SNP) | VAF 95/185 reads (51%) | catalogued as COSV52883538; called by muse, mutect2, varscan2
- ZNF616 | c.541A>C p.R181= | Silent (SNP) | VAF 217/536 reads (40%) | catalogued as COSV57510053; called by muse, mutect2, varscan2
